Gene-level copy-number profile of tumor specimen TCGA-29-1697-01A from TCGA case TCGA-29-1697, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 62.8 years (22,933 days).
Specimen TCGA-29-1697-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1f92e42b-0684-4c2d-b4b4-353d83d7a891.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1697-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8bf0f851-6549-417c-810b-3a0b5cd81841

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 2: 18; copy number 3: 22,334; copy number 4: 401; copy number 5: 6,973; copy number 6: 28,335; copy number 7: 7; copy number 8: 57; copy number 9: 1,594; copy number 10: 2; copy number 11: 41; copy number 12: 1; copy number 13: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1697-01A-01D-0559-01): tumor purity 0.98, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:150,078,445–150,257,438, 2 genes: DCLK2, RNU7-194P.
- chr10:34,663,859–35,572,669, 21 genes (within-gene range 0–3): RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1.
- chr17:61,034,636–61,135,969, 4 genes: AC005884.1, AC005884.2, RPL23AP74, AC005856.1.
- chr19:94,062–344,815, 17 genes (within-gene range 0–3): OR4G3P, OR4G1P, OR4F17, WBP1LP11, OR4F8P, AC092192.1, SEPTIN14P19, CICP19, AC092299.1, AC010507.1, LINC01002, AC010507.2, RNU6-1076P, AC016588.2, PLPP2, MIER2, AC016588.1.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:119,730,774–120,445,402, 11 genes, copy number 13 (within-gene range 6–13): TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
